Somatic mutation profile of tumor specimen TARGET-20-PATHWS-09A (aliquot TARGET-20-PATHWS-09A-01D) from TARGET case TARGET-20-PATHWS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,906 days).
Specimen TARGET-20-PATHWS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05d1b659-863c-4634-9fc0-8ca56e03e2c7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATHWS-14A (Bone Marrow Normal), aliquot TARGET-20-PATHWS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3d1d5a7-4850-4b1c-865e-836aef6f16f5

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 2, Missense Mutation 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KIT | c.1594_1595insGG p.V532Gfs*2 | Frame Shift Ins (INS) | VAF 22/115 reads (19%) | called by mutect2, varscan2*
- KIT | c.1595_1596insTTGA p.A533* | Nonsense Mutation (INS) | VAF 22/117 reads (19%) | called by mutect2, pindel*, varscan2*
- STAG2 | c.175_176dup p.G60Efs*12 | Frame Shift Ins (INS) | VAF 30/48 reads (63%) | called by mutect2, pindel, varscan2
- IKZF1 | c.183T>C p.T61= | Silent (SNP) | VAF 9/66 reads (14%) | called by mutect2, varscan2
